FM case AD15503 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/9b5208b1-8523-4799-b1ab-830baa38c9da

Female, 39.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; metastasis. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
